Somatic mutation profile of tumor specimen TCGA-13-1481-01A (aliquot TCGA-13-1481-01A-01W-0549-09) from TCGA case TCGA-13-1481, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.4 years (27,898 days).
Specimen TCGA-13-1481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caa9e94c-3ccb-4c2f-8e3d-fe2f66228ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1481-10A (Blood Derived Normal), aliquot TCGA-13-1481-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40f0f470-7a00-4945-b64e-63c432bf64dc

The open-access MAF lists 231 somatic variants for this specimen: 189 protein-altering or splice-affecting, 34 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 34, Nonsense Mutation 12, Splice Site 7, Frame Shift Del 6, Splice Region 3, Intron 2, In Frame Del 2, RNA 2, 3'Flank 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8090_8105del p.S2697Kfs*31 | Frame Shift Del (DEL) | VAF 142/343 reads (41%) | catalogued as rs1555286989; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD2 | c.701G>C p.C234S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV61775717; called by muse, mutect2, varscan2
- ADAM30 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101023830; called by muse, mutect2
- ADCY8 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs748910830, COSV99651897; called by muse, mutect2
- AHCTF1 | c.5046T>A p.S1682R (on ENST00000366508; = p.S1656R on NM_015446.5) | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58253728; called by muse, mutect2, varscan2
- ALX1 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100374376; called by muse, mutect2
- ANGPTL4 | c.529A>C p.N177H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV56845456; called by muse, mutect2, varscan2
- ANXA1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.206); catalogued as rs1224222319, COSV99973910; called by muse, mutect2
- AOX1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV101021909; called by muse, mutect2
- AP4B1 | c.467T>G p.V156G | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV56726472; called by muse, mutect2, varscan2
- ARHGAP21 | c.2341G>C p.V781L | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV100256102, COSV100256129; called by muse, mutect2
- ARHGAP5 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV61538581; called by muse, mutect2, varscan2
- ATP5F1C | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV100184309; called by muse, mutect2
- ATXN7 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV99894284; called by muse, mutect2
- BDKRB2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV60016519; called by muse, mutect2, varscan2
- BNIP5 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV71325790, COSV71325809; called by muse, mutect2, varscan2
- C2CD3 | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1192421094, COSV100486541; called by muse, mutect2
- CAD | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53030606; called by muse, mutect2, varscan2
- CAMK1G | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755683128, COSV99151671; called by muse, mutect2, varscan2
- CAPN10 | c.996A>G p.T332= | Splice Region (SNP) | VAF 6/10 reads (60%) | catalogued as rs1158033383, COSV54378920; called by muse, mutect2
- CCDC178 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as rs1204139151, COSV100284605, COSV55777457, COSV55796096; called by muse, mutect2
- CCDC87 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV59580147; called by muse, mutect2
- CCDC88A | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55067650; called by muse, mutect2
- CDAN1 | c.3487G>C p.E1163Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV51911591; called by muse, mutect2, varscan2
- CDH6 | c.588A>C p.K196N | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99418906; called by muse, mutect2
- CDK4 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225973; called by muse, mutect2
- CENPF | c.7087A>T p.K2363* | Nonsense Mutation (SNP) | VAF 5/134 reads (4%) | catalogued as COSV100871664; called by muse, mutect2
- CEP41 | c.965A>C p.D322A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99782686; called by muse, mutect2
- CLIP4 | c.1776C>G p.N592K | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV100191834; called by muse, mutect2
- CNNM4 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs374698559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG1 | c.1152C>G p.D384E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs777144980, COSV55431401, COSV55432449; called by muse, mutect2, varscan2
- CPED1 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1436163054, COSV60010166; called by muse, mutect2, varscan2
- CPQ | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99611670; called by muse, mutect2
- CSF3R | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100117643; called by muse, mutect2
- CST6 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV100375882, COSV56413603; called by muse, mutect2
- CTCFL | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV54776259, COSV99712516; called by muse, mutect2
- CWC22 | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 42/550 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99844206; called by muse, mutect2
- DDX10 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100489425; called by muse, mutect2
- DENND4A | c.4645G>C p.D1549H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV71265684; called by muse, mutect2, varscan2
- DIAPH2 | c.2693T>C p.L898P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61286926; called by muse, mutect2, varscan2
- DLGAP1 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100229910, COSV100232387; called by muse, mutect2
- DLGAP3 | c.2649C>G p.I883M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs771631823, COSV52394119, COSV52396550; called by mutect2, varscan2
- DNAAF1 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV57578493; called by muse, mutect2, varscan2
- DNAH8 | c.11859G>C p.Q3953H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100544729, COSV100546686; called by muse, mutect2, varscan2
- DPH2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV52542737, COSV99356213; called by muse, mutect2
- DPP4 | c.1242T>G p.Y414* | Nonsense Mutation (SNP) | VAF 6/130 reads (5%) | catalogued as COSV100858838; called by muse, mutect2
- DPYSL5 | c.1090-1G>C p.X364_splice | Splice Site (SNP) | VAF 18/202 reads (9%) | catalogued as COSV99982260; called by muse, mutect2
- DSP | c.7124G>C p.G2375A | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101131252; called by muse, mutect2
- DYSF | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50587044, COSV99246480; called by muse, mutect2
- EBF2 | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs557856249, COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDEM3 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100545187; called by muse, mutect2
- EFHC2 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs371172012, COSV101375464; called by mutect2, varscan2
- EPHA3 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100344766; called by muse, mutect2
- ERN1 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70504171; called by muse, mutect2, varscan2
- F8 | c.5897T>C p.M1966T | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100811465; called by muse, mutect2
- FBLN5 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50907024; called by muse, mutect2, varscan2
- FBXW8 | c.62T>C p.I21T (on ENST00000309909; = p.I59T on NM_012174.1) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV59302435; called by muse, mutect2, varscan2
- FLG2 | c.4361A>G p.H1454R | Missense Mutation (SNP) | VAF 59/572 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV66171732; called by muse, mutect2, varscan2
- FRMD6 | c.1637A>G p.D546G (on ENST00000344768 / NM_001267046.2; = p.D538G on NM_152330.4) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV61090210; called by muse, mutect2, varscan2
- GLA | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411817589, CM119131; called by muse, mutect2
- GLYATL2 | c.442A>C p.K148Q | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.185); catalogued as rs374045299, COSV54851110; called by muse, mutect2, varscan2
- GPR19 | c.759A>G p.I253M | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV100196862; called by muse, mutect2
- GPRC6A | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100114318; called by muse, mutect2
- GRID2 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56183410; called by muse, mutect2, varscan2
- GRID2 | c.2805G>C p.E935D | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99940088; called by muse, mutect2, varscan2
- H3C10 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV60797691, COSV60798164; called by muse, mutect2, varscan2
- H4C11 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV61827338; called by mutect2, varscan2
- HAVCR1 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.373); catalogued as COSV100208188; called by muse, mutect2
- HECTD4 | c.7234C>A p.P2412T | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101107360; called by muse, mutect2
- HIPK1 | c.210C>G p.Y70* | Nonsense Mutation (SNP) | VAF 34/347 reads (10%) | catalogued as COSV65786412; called by muse, mutect2, varscan2
- HLA-DQA2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100890709; called by muse, mutect2
- HLA-G | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64406559; called by muse, mutect2
- HUWE1 | c.603A>T p.E201D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99471841; called by muse, mutect2
- IGSF9 | c.1981C>T p.R661W (on ENST00000368094 / NM_001135050.2; = p.R645W on NM_020789.4) | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs769032688, COSV63641658; called by muse, mutect2, varscan2
- IL27RA | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 12/245 reads (5%) | catalogued as COSV99652108; called by muse, mutect2
- INKA2 | c.278C>G p.P93R | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV61878817; called by muse, mutect2
- ITIH3 | c.2453A>G p.D818G | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV99819282; called by muse, mutect2
- KAZN | c.1099-1G>T p.X367_splice | Splice Site (SNP) | VAF 15/92 reads (16%) | catalogued as COSV63209646; called by muse, mutect2, varscan2
- KCNT2 | c.1294+1G>A p.X432_splice | Splice Site (SNP) | VAF 16/99 reads (16%) | catalogued as COSV54101225; called by muse, mutect2, varscan2
- KEL | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV62337095; called by muse, mutect2, varscan2
- KHDRBS3 | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63422790; called by muse, mutect2, varscan2
- KIAA0753 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV100810578; called by muse, mutect2
- KIF5A | c.2447A>C p.E816A | Missense Mutation (SNP) | VAF 32/781 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV99672862; called by muse, mutect2
- KIF6 | c.1492A>T p.M498L | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs759461166, COSV99758489; called by muse, mutect2
- KIRREL1 | c.2171A>G p.Y724C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1558021032, COSV100779816; called by muse, mutect2
- LRRC8C | c.1848A>T p.E616D | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100968216; called by muse, mutect2
- MACF1 | c.6856G>C p.E2286Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV99243708; called by muse, mutect2
- MDN1 | c.15574G>C p.D5192H | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101021217; called by muse, mutect2
- MGAT4C | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV59836269; called by muse, mutect2, varscan2
- MORF4L1 | c.646A>T p.R216W (on ENST00000331268 / NM_206839.2; = p.R177W on NM_006791.4) | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.181); catalogued as COSV100489102; called by muse, mutect2
- MRPL46 | c.516A>G p.I172M | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100363741; called by muse, mutect2
- MYT1L | c.1457A>T p.H486L | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as COSV67729169; called by muse, mutect2, varscan2
- MYT1L | c.711T>G p.S237R | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV67729174; called by muse, mutect2, varscan2
- NACA | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV63268882, COSV63272062; called by muse, mutect2, varscan2
- NDUFB11 | c.422G>T p.C141F (on ENST00000377811 / NM_001135998.3; = p.C151F on NM_019056.6) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99333299; called by muse, mutect2
- NEDD4L | c.1328G>A p.R443Q (on ENST00000400345 / NM_001144967.3; = p.R423Q on NM_015277.6) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV99894077; called by muse, mutect2
- NKIRAS2 | c.302A>T p.K101M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56918305; called by muse, mutect2, varscan2
- NKTR | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs751499916, COSV51774367; called by muse, mutect2, varscan2
- NLRC5 | c.4226G>T p.S1409I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV52660962; called by muse, mutect2, varscan2
- NLRP13 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1171946395, COSV100738191; called by muse, mutect2
- NPR2 | c.2878G>T p.V960F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52415392; called by muse, mutect2, varscan2
- NR6A1 | c.844G>T p.E282* (on ENST00000487099 / NM_033334.4; = p.E277* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 12/125 reads (10%) | catalogued as COSV60636521; called by muse, mutect2, varscan2
- NTNG1 | c.858C>G p.Y286* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV53983712, COSV53985417, COSV99638802; called by muse, mutect2, varscan2
- NUP160 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.079); catalogued as COSV65855514; called by muse, mutect2, varscan2
- NXF3 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV101221933; called by muse, mutect2, varscan2
- OAS1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs148820389; called by muse, mutect2, varscan2
- OR13C5 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as COSV66165190; called by muse, mutect2, varscan2
- OR4K2 | c.854T>A p.I285K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV53851029; called by muse, mutect2, varscan2
- OR6C6 | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100626456; called by muse, mutect2
- OR8D1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV100766627, COSV63443224; called by muse, mutect2
- OSBPL1A | c.853A>C p.T285P | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV60202108; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1183G>C p.G395R (on ENST00000259318 / NM_001136562.3; = p.G626R on NM_007203.5) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.47); catalogued as COSV52180258; called by muse, mutect2, varscan2
- PCDH12 | c.2976C>T p.S992= | Splice Region (SNP) | VAF 7/31 reads (23%) | catalogued as COSV51523647; called by muse, mutect2, varscan2
- PCDHA9 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs782326884, COSV100969423; called by muse, mutect2, varscan2
- PCDHGA5 | c.2260T>G p.S754A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV54007533; called by muse, mutect2, varscan2
- PDGFRA | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs139465754; called by muse, mutect2
- PHKA1 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs782789642, COSV59809727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLDB1 | c.1836G>C p.Q612H | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100616479; called by muse, varscan2
- PHLDB1 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782004738, COSV61876602; called by muse, varscan2
- PKDREJ | c.4154A>G p.N1385S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767231597, COSV53552022; called by muse, mutect2, varscan2
- PRKCI | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.327); catalogued as COSV99855823; called by muse, mutect2
- PRPH2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100028063; called by muse, mutect2
- PSME1 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52825431; called by muse, mutect2, varscan2
- QSOX2 | c.1419C>A p.F473L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62394995; called by muse, mutect2, varscan2
- RAI14 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99462814; called by muse, mutect2
- RALGAPB | c.3933C>G p.D1311E | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53440988; called by muse, mutect2
- RARA | c.1140G>C p.K380N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54195769; called by mutect2, varscan2
- RASSF2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RGS6 | c.459+2T>G p.X153_splice | Splice Site (SNP) | VAF 34/310 reads (11%) | catalogued as COSV100666029; called by muse, mutect2, varscan2
- RIT2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56306183; called by muse, mutect2, varscan2
- RNF213 | c.8004G>T p.K2668N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV60406030; called by muse, mutect2, varscan2
- ROR1 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 50/882 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100935159; called by muse, mutect2
- RPS6KC1 | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100873864; called by muse, mutect2
- RUNX1 | c.784G>A p.G262R (on ENST00000344691 / NM_001001890.3; = p.G289R on NM_001754.5) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV55887169, COSV55893494; called by muse, mutect2
- SAMD9 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101180250, COSV66077098; called by muse, mutect2, varscan2
- SAMHD1 | c.1512A>T p.Q504H (on ENST00000262878 / NM_001363729.2; = p.Q539H on NM_015474.4) | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV99455895; called by muse, mutect2
- SAMSN1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53475849; called by muse, mutect2, varscan2
- SBSPON | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99817500; called by muse, mutect2
- SI | c.5190G>C p.E1730D | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100015262; called by muse, mutect2
- SLC12A5 | c.2520C>A p.N840K (on ENST00000454036 / NM_001134771.2; = p.N817K on NM_020708.5) | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV99715880; called by muse, mutect2
- SLC13A3 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 126/660 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.388); catalogued as COSV51721219; called by muse, mutect2, varscan2
- SLC38A4 | c.662A>T p.Y221F | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99872666; called by muse, mutect2
- SLC6A6 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100692110; called by muse, mutect2
- SLC7A7 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99591652; called by muse, mutect2
- SLCO1B3 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV53935064, COSV99680771; called by muse, mutect2
- SNRPF | c.4-1G>C p.X2_splice | Splice Site (SNP) | VAF 7/119 reads (6%) | catalogued as COSV99900056, COSV99900077; called by muse, mutect2
- SOD1 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV99532105; called by muse, mutect2
- SPAG1 | c.1742C>A p.S581* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as COSV52562229; called by muse, mutect2, varscan2
- STEAP2 | c.1087T>A p.F363I | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV55293042; called by muse, mutect2, varscan2
- SUCO | c.233T>A p.L78* | Nonsense Mutation (SNP) | VAF 10/252 reads (4%) | catalogued as COSV99742664; called by muse, mutect2
- TAF1A | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100600971; called by muse, mutect2
- TAPBP | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV70457616; called by muse, mutect2, varscan2
- TBX20 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68784459, COSV68784920; called by muse, mutect2
- TBXAS1 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV54951747; called by muse, mutect2, varscan2
- TEK | c.3040G>T p.V1014L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66232076; called by muse, mutect2, varscan2
- TENT2 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57138866; called by mutect2, varscan2
- TG | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 30/507 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV99600460; called by muse, mutect2
- TIMM44 | c.1239G>T p.P413= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54494609, COSV99564018; called by muse, mutect2
- TMEM132B | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.44); catalogued as COSV100169447; called by muse, mutect2
- TUBB8 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59117397; called by muse, mutect2, varscan2
- TYRO3 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1342953036, COSV99777546; called by muse, mutect2
- UBR4 | c.6506A>C p.E2169A | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64396398; called by muse, mutect2, varscan2
- WDR1 | c.1631A>G p.N544S (on ENST00000382452; = p.N404S on NM_005112.5) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.333); catalogued as rs751892881, COSV66726008; called by muse, mutect2, varscan2
- YAP1 | c.1510T>A p.L504I (on ENST00000282441 / NM_001130145.3; = p.L450I on NM_006106.5) | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56778002; called by muse, mutect2, varscan2
- YWHAB | c.670A>T p.R224W | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99407762; called by muse, mutect2
- ZBBX | c.811A>C p.T271P | Missense Mutation (SNP) | VAF 38/700 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs770854747, COSV100283856; called by muse, mutect2
- ZDHHC14 | c.1006C>G p.Q336E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV58195941; called by muse, mutect2, varscan2
- ZMIZ1 | c.2289C>A p.C763* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV57901764; called by muse, mutect2, varscan2
- ZNF169 | c.677G>C p.S226T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV61765933; called by muse, mutect2, varscan2
- ZNF217 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV100184412; called by muse, mutect2
- ZNF32 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV65641883; called by muse, mutect2, varscan2
- ZNF462 | c.3511G>A p.A1171T | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1468407217, COSV52948224; called by muse, mutect2, varscan2
- ZNF570 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100356140; called by muse, mutect2
- ZNF878 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101521189; called by muse, mutect2
- ZSCAN25 | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53554139; called by muse, mutect2, varscan2
- AGBL5 | c.20del p.G7Dfs*13 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- AHSG | c.676-4_683del p.X226_splice | Splice Site (DEL) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4491_4504del p.Y1498Gfs*4 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- FBXO28 | c.811_835del p.N271Gfs*26 | Frame Shift Del (DEL) | VAF 36/338 reads (11%) | called by mutect2, pindel
- GCNT2 | c.396_404del p.T133_A135del | In Frame Del (DEL) | VAF 30/270 reads (11%) | called by mutect2, pindel, varscan2
- GPBP1 | c.1304del p.N435Mfs*3 | Frame Shift Del (DEL) | VAF 52/185 reads (28%) | called by mutect2, pindel, varscan2
- IGLV3-22 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- KMO | c.1299_1300insCT p.A434Lfs*21 | Frame Shift Ins (INS) | VAF 29/395 reads (7%) | called by mutect2, pindel*
- MPHOSPH10 | c.721_724del p.D241Lfs*23 | Frame Shift Del (DEL) | VAF 33/220 reads (15%) | called by mutect2, pindel, varscan2
- MRTFB | c.70_81del p.Q24_A27del | In Frame Del (DEL) | VAF 47/115 reads (41%) | called by mutect2, pindel, varscan2
- PAK5 | c.1616+1del p.X539_splice | Splice Site (DEL) | VAF 15/182 reads (8%) | called by mutect2, pindel*
- POTEA | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- UBR1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ALPK1 | c.2544C>T p.A848= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV51590104; called by muse, mutect2, varscan2
- CD5L | c.975C>T p.C325= | Silent (SNP) | VAF 25/308 reads (8%) | catalogued as rs1484414919, COSV100941042; called by muse, mutect2
- CERKL | c.1608C>T p.V536= (on ENST00000339098 / NM_001030311.2; = p.V510= on NM_201548.5) | Silent (SNP) | VAF 28/398 reads (7%) | catalogued as COSV59211536; called by muse, mutect2
- CFAP58 | c.2217C>T p.S739= | Silent (SNP) | VAF 27/314 reads (9%) | catalogued as COSV100866107; called by muse, mutect2
- DPY19L3 | c.2058G>A p.E686= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as COSV60479263; called by muse, mutect2, varscan2
- ELAVL4 | c.681G>A p.Q227= | Silent (SNP) | VAF 25/290 reads (9%) | catalogued as COSV100836719; called by muse, mutect2
- FILIP1 | c.135G>A p.K45= | Silent (SNP) | VAF 55/632 reads (9%) | called by muse, mutect2
- GABRE | c.324T>A p.P108= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV64820882; called by muse, mutect2
- GABRQ | c.1440C>A p.T480= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as COSV100941214; called by muse, mutect2
- GP1BA | c.93G>C p.V31= | Silent (SNP) | VAF 23/398 reads (6%) | catalogued as COSV99850981; called by muse, mutect2
- ITSN2 | c.4230G>A p.A1410= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs761387506, COSV61952356; called by muse, mutect2, varscan2
- KALRN | c.2994G>C p.R998= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV99563785; called by muse, mutect2, varscan2
- KDM8 | c.771G>A p.E257= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV99619518; called by muse, mutect2
- KRT3 | c.129T>C p.Y43= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1249213871, COSV100527021; called by muse, mutect2
- MAGEC3 | c.1224G>A p.P408= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1480581331, COSV100025302; called by muse, mutect2, varscan2
- MPO | c.1387C>T p.L463= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV56567550; called by muse, mutect2, varscan2
- MRPS5 | c.1221C>T p.D407= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV55535035; called by muse, mutect2, varscan2
- MUC17 | c.15G>A p.G5= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV59331525, COSV59332200; called by muse, mutect2, varscan2
- NCKAP5 | c.2796T>A p.P932= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV58466538; called by muse, mutect2, varscan2
- NECAB2 | c.1093C>T p.L365= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs1241157145, COSV59422705; called by muse, mutect2, varscan2
- POLR3C | c.1059C>T p.V353= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs782081848, COSV100492880; called by muse, mutect2
- PRRC2A | c.1221C>G p.A407= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100784611, COSV63224955, COSV63225032; called by muse, mutect2, varscan2
- PTER | c.480C>G p.T160= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as COSV100126643; called by muse, mutect2
- RBM15 | c.2928G>A p.L976= | Silent (SNP) | VAF 27/251 reads (11%) | catalogued as COSV63924188; called by muse, mutect2, varscan2
- SLC11A1 | c.819C>T p.R273= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV51918747; called by muse, mutect2, varscan2
- SLC6A13 | c.165C>G p.V55= | Silent (SNP) | VAF 42/280 reads (15%) | catalogued as COSV100569893; called by muse, mutect2, varscan2
- STAG3 | c.891T>C p.I297= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100425867; called by muse, mutect2
- STON1-GTF2A1L | c.2613A>G p.V871= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV59135873; called by muse, mutect2, varscan2
- TEX101 | c.57C>G p.L19= (on ENST00000598265 / NM_001130011.3; = p.L37= on NM_031451.4) | Silent (SNP) | VAF 38/628 reads (6%) | catalogued as COSV99494784; called by muse, mutect2
- TMEM74B | c.165C>A p.T55= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV67892190; called by muse, mutect2, varscan2
- TTL | c.249A>T p.T83= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99271224; called by muse, mutect2
- TUBGCP4 | c.195T>C p.H65= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV53020792; called by muse, mutect2, varscan2
- ZNF461 | c.855C>T p.G285= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV100831407; called by muse, mutect2, varscan2
- ZZEF1 | c.5460A>C p.G1820= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV101067745; called by muse, mutect2
- CEP295 | chr11:93735121 C>T | 3'Flank (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- FGF13 | c.403-32138G>T | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59549195; called by muse, mutect2, varscan2
- FRMPD2B | n.1210G>T | RNA (SNP) | VAF 78/693 reads (11%) | called by mutect2, varscan2
- GDA | c.*2408G>A | 3'UTR (SNP) | VAF 102/261 reads (39%) | catalogued as COSV99429144; called by muse, mutect2, varscan2
- GLYATL1 | c.-126C>T | 5'UTR (SNP) | VAF 8/95 reads (8%) | catalogued as rs978361510, COSV100265286; called by muse, mutect2
- NRP2 | c.2440+9567C>T | Intron (SNP) | VAF 43/198 reads (22%) | catalogued as COSV55933584; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792459 C>T | 3'Flank (SNP) | VAF 11/109 reads (10%) | catalogued as rs1200970004; called by muse, mutect2, varscan2
- SSPOP | n.974G>A | RNA (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100022423; called by muse, mutect2
